Gene-level copy-number profile of tumor specimen C3L-01043-01 from CPTAC case C3L-01043, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 59.0 years (21,551 days).
Specimen C3L-01043-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e1da391f-86fe-4393-b6e1-b33acbb5529a.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01043-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,705 have no estimate.
https://portal.gdc.cancer.gov/files/f703ebad-21a6-4930-a9c2-30a95bff4793

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 87; copy number 1: 5,574; copy number 2: 50,488; copy number 3: 2,734; copy number 4: 5; copy number 5: 4; copy number 7: 3; copy number 35: 23.

Homozygous deletions (total copy number 0; autosomes only): 85 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,895,800–23,956,444, 82 genes (broad region; genes not listed).
- chr10:79,703,227–79,714,681, 1 gene (within-gene range 0–1): NUTM2B.
- chr10:87,817,928–87,845,612, 2 genes (within-gene range 0–1): CFL1P1, RN7SL78P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 30 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:43,112,629–43,566,001, 1 gene, copy number 5 (within-gene range 2–5): HECW1.
- chr7:43,274,159–43,650,713, 3 genes, copy number 5 (within-gene range 2–5): AC004692.1, LUARIS, STK17A.
- chr7:53,655,508–55,260,256, 23 genes, copy number 35: LINC01446, RNU2-29P, RAC1P9, AC074348.1, HAUS6P3, LINC02854, AC092848.2, AC092848.1, LINC01445, SLC25A5P3, VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2.
- chr7:55,365,448–55,433,742, 1 gene, copy number 7: LANCL2.
- chr7:56,288,230–56,305,526, 2 genes, copy number 7: AC073136.1, AC073136.2.

Autosomal genes at a single copy (total copy number 1): 2,720. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
